Gene-level copy-number profile of tumor specimen C3L-03639-01 (profiled together with C3L-03639-02, C3L-03639-03) from CPTAC case C3L-03639, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 76.0 years (27,761 days).
Specimen C3L-03639-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dd4536dc-f25d-4481-98d1-229908a5c400.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03639-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/f97fffe2-93d1-4c84-9746-98c124f8651f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 455; copy number 1: 58; copy number 2: 4,298; copy number 3: 860; copy number 4: 28,589; copy number 5: 8,009; copy number 6: 13,023; copy number 7: 1,402; copy number 8: 1,654; copy number 9: 4; copy number 10: 78; copy number 11: 52; copy number 12: 7; copy number 14: 69; copy number 16: 12; copy number 17: 8; copy number 20: 64; copy number 22: 59; copy number 23: 15; copy number 25: 2; copy number 26: 82; copy number 30: 25; copy number 31: 22; copy number 35: 4; copy number 36: 12; copy number 39: 25; copy number 47: 2; copy number 60: 10.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr18:50,968,019–51,085,045, 2 genes (within-gene range 0–6): AC091551.1, SMAD4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 552 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,769,083, 17 genes, copy number 10–17: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P.
- chr1:143,811,359–143,846,504, 2 genes, copy number 11–17: AC239798.1, AC239798.2.
- chr1:143,929,994–144,068,350, 3 genes, copy number 9: RPL22P5, FAM72C, SRGAP2D.
- chr4:49,203,171–49,203,726, 1 gene, copy number 9: AC118282.3.
- chr5:34,915,677–45,696,498, 166 genes, copy number 16–39 (within-gene range 4–39) (broad region; genes not listed).
- chr8:7,926,337–7,952,413, 2 genes, copy number 16: ZNF705B, DEFB108A.
- chr11:67,317,871–70,436,584, 121 genes, copy number 20–36 (broad region; genes not listed).
- chr11:72,239,077–72,573,229, 14 genes, copy number 35–60 (within-gene range 2–60): PHOX2A, AP000593.2, AP000593.4, AP000593.1, CLPB, AP000593.3, AP002892.2, AP002892.1, AP003785.1, ART2BP, ART2P, AP005019.2, AP005019.1, LINC01537.
- chr11:77,514,936–78,582,156, 37 genes, copy number 25–47: CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3.
- chr14:18,333,726–19,714,332, 69 genes, copy number 10 (broad region; genes not listed).
- chr16:55,760,566–55,793,960, 1 gene, copy number 11: CES1P1.
- chr19:37,217,926–38,304,910, 41 genes, copy number 11 (within-gene range 5–11): ZNF383, AC016590.1, LINC01535, ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1, WDR87, SIPA1L3, AC008395.1, AC011465.1, AC011479.3, AC011479.2, RN7SL663P, DPF1, SPINT2, PPP1R14A, AC011479.1, AC011479.4, Y_RNA.
- chr19:38,817,471–38,840,178, 1 gene, copy number 14 (within-gene range 7–14): AC008982.1.
- chr19:38,836,388–39,846,379, 68 genes, copy number 14 (broad region; genes not listed).
- chr21:10,482,738–13,067,033, 9 genes, copy number 11 (within-gene range 5–11): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
